Somatic mutation profile of tumor specimen 0DNHH5 from CCDI case PBCBEL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.7 years (6,483 days).
Specimen 0DNHH5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1b94074-0f83-41e2-81e2-44840fcfe4b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNHGT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fd85735-40f3-4d92-9fea-473927e47880

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 3, Splice Site 2, Intron 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 203/449 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALOX5 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.161); catalogued as rs1209164597; called by muse, mutect2, varscan2
- APOC2 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 170/419 reads (41%) | catalogued as CD910633; called by muse, mutect2, varscan2
- FBXW7 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 197/458 reads (43%) | catalogued as rs781123562, COSV55916781; called by muse, mutect2, varscan2
- KCNAB3 | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 138/335 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs758415442; called by muse, mutect2, varscan2
- KDM3B | c.3083G>A p.R1028Q | Missense Mutation (SNP) | VAF 262/524 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100069021; called by muse, mutect2, varscan2
- MAGEC3 | c.1894A>T p.S632C | Missense Mutation (SNP) | VAF 175/382 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV100025979; called by muse, mutect2, varscan2
- MUC5B | c.9425C>A p.A3142D | Missense Mutation (SNP) | VAF 102/306 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as rs772452469, COSV101499942; called by muse, varscan2
- MYOCD | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 216/438 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763545671; called by muse, mutect2, varscan2
- NGFR | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 23/349 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99412839; called by muse, mutect2
- NRF1 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 268/600 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV104384372; called by muse, mutect2, varscan2
- PCDHGA6 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 220/435 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs769494929, COSV54021949; called by muse, mutect2, varscan2
- SLC7A3 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 150/357 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as rs368079498, COSV53226632; called by muse, mutect2, varscan2
- SUFU | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 349/364 reads (96%) | catalogued as CM127600; called by muse, mutect2, varscan2
- TYSND1 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 180/332 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs750932595; called by muse, mutect2, varscan2
- VPS51 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 120/289 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs769644606, COSV54207773; called by muse, mutect2, varscan2
- ANGPTL6 | c.583-2A>T p.X195_splice | Splice Site (SNP) | VAF 162/346 reads (47%) | called by muse, mutect2, varscan2
- CEACAM1 | c.1235T>C p.L412P | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAH8 | c.8245G>A p.E2749K | Missense Mutation (SNP) | VAF 233/505 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- FSCN3 | c.1120+2T>C p.X374_splice | Splice Site (SNP) | VAF 224/533 reads (42%) | called by mutect2, varscan2
- ITSN1 | c.4499G>A p.G1500D | Missense Mutation (SNP) | VAF 278/589 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PCNT | c.4115dup p.Q1373Afs*54 | Frame Shift Ins (INS) | VAF 106/279 reads (38%) | called by mutect2, pindel, varscan2
- TTC6 | c.1561C>A p.Q521K | Missense Mutation (SNP) | VAF 156/420 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- ADRA1D | c.933G>A p.A311= | Silent (SNP) | VAF 101/226 reads (45%) | called by muse, mutect2, varscan2
- ASCC2 | c.1488C>T p.Y496= | Silent (SNP) | VAF 146/338 reads (43%) | catalogued as rs149577921; called by muse, mutect2, varscan2
- FAM118B | c.57C>T p.N19= | Silent (SNP) | VAF 309/660 reads (47%) | catalogued as rs1565330719; called by muse, mutect2, varscan2
- KCNF1 | c.48C>T p.S16= | Silent (SNP) | VAF 81/173 reads (47%) | called by muse, mutect2, varscan2
- OR4D9 | c.537C>T p.C179= | Silent (SNP) | VAF 161/433 reads (37%) | catalogued as rs145873782, COSV100259733; called by muse, varscan2
- SH3PXD2A | c.1665G>A p.E555= (on ENST00000369774 / NM_001365079.1; = p.E527= on NM_014631.2) | Silent (SNP) | VAF 251/260 reads (97%) | catalogued as rs1394256077; called by muse, mutect2, varscan2
- STAT1 | c.1344C>T p.L448= | Silent (SNP) | VAF 232/534 reads (43%) | catalogued as rs773084786, COSV63115798; called by muse, mutect2, varscan2
- BAIAP2L1 | c.956-41C>A | Intron (SNP) | VAF 100/215 reads (47%) | called by muse, mutect2, varscan2
- SLC5A1 | c.*6A>G | 3'UTR (SNP) | VAF 102/218 reads (47%) | catalogued as rs1330166504; called by muse, mutect2, varscan2
